Gene-level copy-number profile of tumor specimen TCGA-22-4599-01A from TCGA case TCGA-22-4599, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 73.7 years (26,925 days).
Specimen TCGA-22-4599-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.ac665350-afd5-4b09-a082-91187f3a4cb9.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-4599-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2ade0b59-2bf9-4214-abab-a62126f8d520

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 217; copy number 2: 26,069; copy number 3: 16,261; copy number 4: 4,994; copy number 5: 2,961; copy number 6: 6,638; copy number 7: 719; copy number 8: 1,801; copy number 10: 121; copy number 11: 29.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-4599-01A-01D-1439-01): tumor purity 0.47, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:71,281,389–71,390,436, 3 genes (within-gene range 0–2): CMTR2, AC106736.1, CALB2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 12,269 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–6 (broad region; genes not listed).
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 8 (broad region; genes not listed).
- chr5:58,198–45,895,970, 710 genes, copy number 5 (broad region; genes not listed).
- chr7:70,972–159,233,377, 3,014 genes, copy number 5–6 (broad region; genes not listed).
- chr11:101,029,624–135,075,908, 747 genes, copy number 5–8 (broad region; genes not listed).
- chr12:220,621–40,369,285, 876 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr13:63,667,681–64,076,044, 11 genes, copy number 6: LINC00395, OR7E156P, AL445989.2, AL445989.1, RNU6-81P, PPP1R2P10, AL445238.2, OR7E104P, AL445238.1, LINC00355, NFYAP1.
- chr17:69,232,963–83,095,122, 483 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:21,825,487–21,831,539, 1 gene, copy number 11 (within-gene range 4–11): MIR133A1HG.
- chr18:21,829,004–28,177,946, 115 genes, copy number 7–11 (broad region; genes not listed).
- chr18:28,651,732–28,653,208, 1 gene, copy number 7: ARIH2P1.
- chr19:27,638,483–58,605,223, 1,686 genes, copy number 6–10 (broad region; genes not listed).
- chr20:87,250–9,530,524, 221 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 217. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
